Somatic mutation profile of tumor specimen TCGA-ZH-A8Y5-01A (aliquot TCGA-ZH-A8Y5-01A-11D-A417-09) from TCGA case TCGA-ZH-A8Y5, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 69.2 years (25,268 days).
Specimen TCGA-ZH-A8Y5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e5a63ab-1f5c-411f-b30e-ade76ab73d7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZH-A8Y5-10A (Blood Derived Normal), aliquot TCGA-ZH-A8Y5-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3200b0ca-563d-4820-aa24-dd1d7d3f5e35

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 1, In Frame Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO7 | c.343G>A p.V115I (on ENST00000274979; = p.V60I on NM_001001666.4) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs149691575; called by muse, mutect2, varscan2
- CACNA1G | c.4441G>A p.V1481I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772369809, COSV100662427; called by muse, mutect2, varscan2
- DPY19L3 | c.701A>G p.N234S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs976233688; called by muse, mutect2, varscan2
- LAMA5 | c.9401G>T p.R3134L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs535545260, COSV53361977; called by muse, mutect2, varscan2
- MINAR1 | c.876G>T p.K292N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100549236; called by muse, mutect2
- NXPE3 | c.1217G>T p.R406L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149452985, COSV56290606; called by muse, mutect2, varscan2
- PDE9A | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765054468; called by muse, mutect2, varscan2
- UGT2B17 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs770680304, COSV58502372; called by muse, mutect2, varscan2
- ANKRD12 | c.1319C>G p.S440C | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ART5 | c.450C>A p.C150* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- ATP13A3 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP43 | c.1066G>A p.G356S | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIM2 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- NRIP1 | c.2184dup p.E729Rfs*8 | Frame Shift Ins (INS) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- PRDM1 | c.1665C>A p.N555K | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- PRMT3 | c.919A>G p.T307A | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TSC1 | c.1081T>G p.S361A | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- WDR25 | c.651_663delinsA p.S218_I221del | In Frame Del (DEL) | VAF 19/24 reads (79%) | called by pindel, varscan2*
- DKKL1 | c.570C>T p.L190= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- FFAR3 | c.855C>T p.A285= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs766085802; called by muse, mutect2, varscan2
- VENTX | c.324C>T p.G108= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs560345091, COSV58084031; called by muse, mutect2, varscan2
- VPS26B | c.588G>C p.L196= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.*52G>A | 3'UTR (SNP) | VAF 15/39 reads (38%) | catalogued as rs1452245261; called by muse, mutect2, varscan2
